Gene-level copy-number profile of tumor specimen TCGA-68-7755-01A from TCGA case TCGA-68-7755, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-68-7755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.023c8a5e-a775-4439-8ae3-4c74734ad39d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-68-7755-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b7a3ce0-26aa-4f69-8307-f37a7cbe08b3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 502; copy number 2: 12,142; copy number 3: 13,348; copy number 4: 26,577; copy number 5: 5,017; copy number 6: 339; copy number 7: 667; copy number 8: 132; copy number 9: 99; copy number 10: 83; copy number 11: 360; copy number 12: 116; copy number 13: 225; copy number 20: 7; copy number 24: 163; copy number 26: 3; copy number 28: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-68-7755-01A-11D-2121-01): tumor purity 0.62, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,091 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,761,100–149,968,385, 1 gene, copy number 12 (within-gene range 7–12): ANKUB1.
- chr3:149,812,770–152,496,813, 61 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr3:164,978,898–178,937,352, 183 genes, copy number 10–12 (within-gene range 6–12) (broad region; genes not listed).
- chr3:181,534,177–183,884,933, 50 genes, copy number 11 (within-gene range 6–11): AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL.
- chr3:184,132,942–185,938,103, 50 genes, copy number 10: AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B.
- chr7:53,655,508–86,864,884, 640 genes, copy number 10–28 (within-gene range 8–28) (broad region; genes not listed).
- chr7:101,815,904–106,770,207, 106 genes, copy number 9–20 (within-gene range 3–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
